Surgical pathology report (de-identified scan), TCGA case TCGA-CK-4948, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Harvard, specimen TCGA-CK-4948-01B (Primary Tumor).

[REDACTED]

Accession Number: [REDACTED]

Type: Surgical Pathology

Pathology Report

COLON, SEGMENTAL RESECT FOR TUMOR

Accessioned On: [REDACTED]

DIAGNOSIS:

SIGMOID COLON, SEGMENTAL COLECTOMY:

INVASIVE ADENOCARCINOMA of the colon (3.5 x 2.5 x 0.6 cm) poorly differentiated,, invading into the subserosa.

Margins of resection are negative for tumor.

Tumor is 0.1 cm from radial margin.

METASTATIC ADENOCARCINOMA in 3 of 20 lymph nodes.

Tumor deposits present in serosa.

The AJCC classification is T3 N1 Mx.

CLINICAL DATA:

History: None given.

Operation: Sigmoid resection

Clinical Diagnosis: Rectal ca

TISSUE SUBMITTED: 1. S [REDACTED]

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "sigmoid colon", is a segment of colon (12 cm in length x 3 cm in diameter) with one stapled resection margin (3.5 cm) and one open end. There is an ulcerated mass with raised, serpiginous borders (3.5 x 2.5 x 0.6 cm) located 3 cm from the opened end and 9.5 cm from the stapled resection margin. The tumor extends into the muscularis propria, grossly. No extension through to the serosal surface is identified. The radial margin is 0.1 cm. The remainder of the colon segment is unremarkable. Representative sections are submitted.

Micro 1: Tumor to open resection margin, perpendicular, 2 frags, [REDACTED]

Micro 2: Stapled resection margin, en face, 2 frags, [REDACTED]

Micro 3-4: Full thickness of tumor to areas of deepest invasion and closest radial margin, 3 frags, [REDACTED]

Micro 5: Tumor to proximal and distal mucosa, 2 frags, [REDACTED]

Micro 6: Uninvolved sigmoid, 3 frags, [REDACTED]

Micro 7: Potential lymph nodes subjacent to tumor, ___ frags, [REDACTED]

Micro 8-11: Lymph nodes, 20 frags, [REDACTED]

[REDACTED]

SPECIMEN TYPE: COLON, SEGMENTAL RESECT FOR TUMOR

Source: NCI Genomic Data Commons file 30582dca-dee4-4160-8938-c3e38b8047e9 (TCGA-CK-4948.31BA7387-DF2F-4D70-B413-3734BA02438E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).